Surgical pathology report (de-identified scan), TCGA case TCGA-44-2661, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2661-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Left upper lobe wedge
- B. Lymph node level 5

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer/breast cancer.

FROZEN SECTION DIAGNOSIS

Lung, left upper lobe, wedge biopsy: Adenocarcinoma.

GROSS DESCRIPTION

A. The specimen is received unfixed labeled "left upper lobe wedge" and consists of a pink and red lung resection specimen measuring 14.4 x 10 x 2.5 cm. There is a slight area of thickening in the central portion of the specimen that is about 1.5 cm in greatest dimension by external palpation. On cut section the central tumor measures 1.5 cm in diameter. Portions of the tumor are taken for research purposes. The margin of resection is grossly free of the disease. A portion of the tumor is taken for frozen section diagnosis. Additional sections after fixation. RS-7

B. The specimen is received in formalin labeled "lymph node level 5" and consists of multiple pieces of black soft tissue measuring 1 cm in greatest aggregate dimension. AS-1.

MICROSCOPIC DESCRIPTION

- A.
- Tumor type: Adenocarcinoma with focal lepidic growth pattern.
- Tumor grade: 1-2 out of 3
- Mitotic Index: 0 mitoses/10 HPFs (1 HPF = 0.19 sq mm)

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

Tumor size: 1.5 cm.
Pulmonary margin of resection: Negative for malignancy
Pleura: Pleural elastosis. Negative for malignancy.
Vascular invasion: Absent
pTNM Stage: T1 N0
Non-tumorous lung: Unremarkable.

Antibody	Results	Comment
TTF-1	Positive	Compatible with lung primary
BRST-2	Negative	
ER	Negative	
PR	Negative	

Paraffin sections; 10% neutral buffered formalin

[A few of the antibodies used in our laboratory may be classified as
analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

B. Portions of the lymph node are negative for malignancy.

4, 3, 14, 20x4

IHC stains added, as shown above, after discussion with [REDACTED].
[REDACTED] [REDACTED] [REDACTED]

DIAGNOSIS

- A. Lung, left upper lobe, excisional biopsy:
Well to moderately differentiated adenocarcinoma.
B. Lymph node, level 5, biopsy: Negative for malignancy.
- [REDACTED]

Source: NCI Genomic Data Commons file 5a2c9904-3efa-424e-b5c8-e582fc78af6b (TCGA-44-2661.17E596F5-74FE-46CC-BEE2-FA1355B01721.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).